Somatic mutation profile of tumor specimen TCGA-17-Z061-01A (aliquot TCGA-17-Z061-01A-01W-0747-08) from TCGA case TCGA-17-Z061, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z061-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6838ad55-7781-450f-930a-da62c9542457.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z061-11A (Solid Tissue Normal), aliquot TCGA-17-Z061-11A-01W-0747-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdb57dab-e3a9-4584-a08d-4803fd1a05c2

The open-access MAF lists 194 somatic variants for this specimen: 139 protein-altering or splice-affecting, 51 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 51, Frame Shift Del 8, Nonsense Mutation 5, Frame Shift Ins 3, Intron 2, RNA 2, Splice Site 1, In Frame Del 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.193A>T p.R65* | Nonsense Mutation (SNP) | VAF 604/627 reads (96%) | catalogued as rs1555526721, COSV52689560; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMP3 | c.772A>G p.S258G | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs1449353517; called by muse, mutect2, varscan2
- BRDT | c.2176C>A p.P726T | Missense Mutation (SNP) | VAF 113/260 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs568472344; called by muse, mutect2, varscan2
- CA4 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 75/76 reads (99%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV99958530; called by muse, mutect2, varscan2
- CAMTA1 | c.1693G>A p.G565S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.144); catalogued as rs143700608; called by muse, mutect2, varscan2
- CYLC1 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV61412818; called by muse, mutect2, varscan2
- EPHA5 | c.2271G>T p.E757D | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56651751; called by muse, mutect2, varscan2
- EVC2 | c.3314T>G p.L1105W | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs745789473; called by muse, mutect2, varscan2
- FAM124B | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1035099098; called by muse, mutect2, varscan2
- FAM167A | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780501946, COSV99034062, COSV99453132; called by muse, mutect2, varscan2
- FAM47C | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.939); catalogued as COSV63723864; called by muse, mutect2, varscan2
- FRMPD1 | c.3277G>C p.E1093Q | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.69); catalogued as rs751807170, COSV66701433; called by muse, mutect2, varscan2
- GAD2 | c.1733T>C p.I578T | Missense Mutation (SNP) | VAF 108/272 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776234244; called by muse, mutect2, varscan2
- HTR1E | c.271G>C p.G91R | Missense Mutation (SNP) | VAF 86/185 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59508821; called by muse, mutect2, varscan2
- KCNB2 | c.2347G>T p.G783W | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV101578783; called by muse, mutect2, varscan2
- KIAA1549L | c.4787G>A p.G1596E (on ENST00000321505; = p.G1893E on NM_012194.3) | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763475566, COSV100381881; called by muse, mutect2, varscan2
- MAGEB4 | c.953G>T p.R318L | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV66775733; called by muse, mutect2, varscan2
- MCM9 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV60164889, COSV60165062; called by muse, mutect2, varscan2
- NCKAP1L | c.485A>G p.H162R | Missense Mutation (SNP) | VAF 205/426 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs1166271320; called by muse, mutect2, varscan2
- OR2T33 | c.954G>T p.R318S | Missense Mutation (SNP) | VAF 188/359 reads (52%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV58815664; called by muse, mutect2, varscan2
- OR4P4 | c.716G>A p.S239N | Missense Mutation (SNP) | VAF 110/239 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100111879; called by muse, mutect2, varscan2
- OR8B2 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100899488; called by muse, mutect2, varscan2
- OR8B3 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV63542316; called by mutect2, varscan2
- PCDH8 | c.3133C>T p.Q1045* | Nonsense Mutation (SNP) | VAF 27/27 reads (100%) | catalogued as COSV100131458; called by muse, mutect2, varscan2
- PCDH9 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 32/32 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV100122490; called by muse, mutect2, varscan2
- PIBF1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 77/83 reads (93%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV100411094; called by muse, mutect2, varscan2
- PPP1R17 | c.381dup p.A128Cfs*19 | Frame Shift Ins (INS) | VAF 35/116 reads (30%) | catalogued as COSV100566382; called by mutect2, pindel, varscan2
- RIF1 | c.1806-1G>T p.X602_splice | Splice Site (SNP) | VAF 171/376 reads (45%) | catalogued as COSV54617313; called by muse, mutect2, varscan2
- RIMS3 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1261332655, COSV65505448; called by muse, mutect2, varscan2
- SERPINA3 | c.1237T>C p.F413L | Missense Mutation (SNP) | VAF 78/230 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV67587296; called by muse, mutect2, varscan2
- SLCO2B1 | c.987del p.S330Lfs*15 | Frame Shift Del (DEL) | VAF 22/55 reads (40%) | catalogued as COSV56933378; called by mutect2, pindel, varscan2
- SORCS1 | c.598G>T p.G200W | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53839738; called by muse, mutect2, varscan2
- SPTA1 | c.5141C>A p.A1714D | Missense Mutation (SNP) | VAF 104/349 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs1193939231; called by muse, mutect2, varscan2
- SYCP2 | c.2197A>G p.I733V | Missense Mutation (SNP) | VAF 123/240 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs754116835; called by muse, mutect2, varscan2
- TEX13A | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV61148073; called by muse, mutect2, varscan2
- UGGT1 | c.3512G>C p.R1171P | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV52132417, COSV52139822; called by muse, mutect2, varscan2
- XIRP2 | c.8545G>T p.V2849L (on ENST00000628543; = p.V3024L on NM_152381.6) | Missense Mutation (SNP) | VAF 133/292 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1384402955; called by muse, mutect2, varscan2
- ZNF44 | c.1618T>G p.C540G (on ENST00000356109 / NM_001164276.2; = p.C492G on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV61135948; called by muse, mutect2, varscan2
- ABCG4 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ADCY8 | c.2299T>G p.L767V | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ADGRB3 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 134/287 reads (47%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- AP1B1 | c.2002G>A p.G668R | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATXN2 | c.3307G>A p.A1103T (on ENST00000550104; = p.A943T on NM_002973.4) | Missense Mutation (SNP) | VAF 79/168 reads (47%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C10orf71 | c.1457G>A p.C486Y | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCM2 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- CD163L1 | c.1792G>T p.V598L | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP161 | c.361C>G p.P121A | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLDN14 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CNTNAP5 | c.3877T>A p.L1293M | Missense Mutation (SNP) | VAF 91/172 reads (53%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CRIM1 | c.2641C>A p.P881T | Missense Mutation (SNP) | VAF 90/223 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTDP1 | c.1029A>T p.K343N | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- DENND2A | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 115/244 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DHRS2 | c.130T>G p.S44A | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.085); called by muse, varscan2
- DIAPH2 | c.1702G>C p.A568P | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLG2 | c.652G>T p.G218* | Nonsense Mutation (SNP) | VAF 128/256 reads (50%) | called by muse, mutect2, varscan2
- DNAH3 | c.1370T>C p.L457P | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DSE | c.1319del p.I440Tfs*45 | Frame Shift Del (DEL) | VAF 28/65 reads (43%) | called by mutect2, pindel, varscan2
- EDN1 | c.611A>T p.Y204F | Missense Mutation (SNP) | VAF 114/305 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- ENOSF1 | c.895G>T p.A299S (on ENST00000340116 / NM_001354066.2; = p.A251S on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPO | c.52T>A p.S18T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EYA4 | c.1244T>A p.M415K (on ENST00000531901 / NM_001301013.1; = p.M409K on NM_004100.5) | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- FAM50A | c.377A>T p.E126V | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FASLG | c.47del p.D16Afs*56 | Frame Shift Del (DEL) | VAF 14/101 reads (14%) | called by pindel, varscan2
- FAT4 | c.14345A>G p.E4782G | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- FBN3 | c.5824C>A p.P1942T | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- FMO1 | c.1444del p.E482Kfs*8 | Frame Shift Del (DEL) | VAF 48/183 reads (26%) | called by mutect2, pindel, varscan2
- FOXR2 | c.196A>T p.S66C | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- GAS7 | c.1291C>T p.H431Y (on ENST00000432992 / NM_201433.2; = p.H291Y on NM_003644.3) | Missense Mutation (SNP) | VAF 43/46 reads (93%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- GIT2 | c.2273A>T p.N758I (on ENST00000355312 / NM_057169.5; = p.N680I on NM_014776.5) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- GORASP2 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- GP2 | c.44G>T p.W15L | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- GRB7 | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 73/75 reads (97%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GYPE | c.194T>C p.V65A | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HGF | c.697C>A p.Q233K | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- HLA-G | c.935T>A p.V312D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- JMJD1C | c.5971G>A p.E1991K | Missense Mutation (SNP) | VAF 112/223 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCNB2 | c.2348G>T p.G783V | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- KDM3B | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); called by muse, mutect2
- KIAA1109 | c.8617A>G p.K2873E | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- KIF7 | c.2038G>T p.A680S | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.86); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KMT2C | c.9722A>G p.Q3241R | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- LRRC25 | c.353G>A p.C118Y | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LYPD5 | c.466T>A p.C156S (on ENST00000377950 / NM_001031749.3; = p.C113S on NM_182573.2) | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MFSD4A | c.1460del p.F487Sfs*32 | Frame Shift Del (DEL) | VAF 149/285 reads (52%) | called by mutect2, pindel, varscan2
- MKRN3 | c.317A>T p.H106L | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC16 | c.39388C>A p.H13130N | Missense Mutation (SNP) | VAF 81/211 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUL1 | c.337T>A p.C113S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.037); called by muse, varscan2
- NCOA3 | c.2062T>G p.L688V | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH3 | c.1821del p.C608Afs*8 | Frame Shift Del (DEL) | VAF 5/8 reads (63%) | called by mutect2, varscan2
- NR5A1 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NRK | c.3664T>A p.L1222M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OGT | c.3025A>G p.T1009A | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- PCDHA1 | c.2275dup p.C759Lfs*3 | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- PGM5 | c.1403G>A p.S468N | Missense Mutation (SNP) | VAF 179/367 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIBF1 | c.1905G>C p.Q635H | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLD2 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 67/73 reads (92%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PLEKHS1 | c.529G>A p.D177N (on ENST00000369310 / NM_182601.1; = p.D183N on NM_024889.5) | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PLN | c.130C>A p.L44M | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PLSCR2 | c.640G>C p.D214H (on ENST00000497985 / NM_001199978.1; = p.D141H on NM_020359.2) | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PRDM13 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMD2 | c.2045G>A p.G682E | Missense Mutation (SNP) | VAF 80/137 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTGFRN | c.1955T>G p.L652R | Missense Mutation (SNP) | VAF 112/217 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PTPRC | c.2878C>A p.Q960K | Missense Mutation (SNP) | VAF 60/112 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PTPRO | c.2861A>T p.H954L (on ENST00000281171 / NM_030667.3; = p.H926L on NM_002848.4) | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- RAB14 | c.357_360del p.I120Sfs*2 | Frame Shift Del (DEL) | VAF 103/257 reads (40%) | called by mutect2, pindel, varscan2
- RB1 | c.396dup p.N133* | Frame Shift Ins (INS) | VAF 12/18 reads (67%) | called by mutect2, pindel, varscan2
- RHBDL2 | c.803T>A p.F268Y | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- RTN4IP1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RYR2 | c.3701A>T p.E1234V | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SIDT1 | c.1530_1535del p.F511_L512del | In Frame Del (DEL) | VAF 96/414 reads (23%) | called by pindel, varscan2
- SLC22A9 | c.875C>A p.P292Q | Missense Mutation (SNP) | VAF 99/199 reads (50%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SLC4A10 | c.2185T>A p.S729T (on ENST00000446997 / NM_001354461.2; = p.S699T on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SMPDL3A | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMYD5 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SOAT1 | c.1020C>G p.I340M | Missense Mutation (SNP) | VAF 209/688 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- SPTBN4 | c.1451G>T p.R484L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SULT1E1 | c.668T>C p.I223T | Missense Mutation (SNP) | VAF 83/317 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- SUPT20HL1 | c.2005G>C p.A669P | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SVEP1 | c.1726A>T p.K576* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- TET2 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 83/161 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- TEX15 | c.6769C>T p.Q2257* (on ENST00000256246; = p.Q2640* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 56/122 reads (46%) | called by muse, mutect2, varscan2
- TFAP2B | c.1032C>A p.H344Q | Missense Mutation (SNP) | VAF 89/181 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRMT2B | c.811G>C p.G271R | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TRPC6 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- TSPAN12 | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 157/312 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- TTN | c.62229C>G p.S20743R (on ENST00000591111; = p.S13319R on NM_003319.4) | Missense Mutation (SNP) | VAF 61/122 reads (50%) | PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- TTN | c.44221A>C p.K14741Q (on ENST00000591111; = p.K7317Q on NM_003319.4) | Missense Mutation (SNP) | VAF 42/92 reads (46%) | PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- TUSC3 | c.939A>T p.I313= | Splice Region (SNP) | VAF 135/266 reads (51%) | called by muse, mutect2, varscan2
- UBQLN2 | c.1048A>G p.T350A | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR93 | c.1474A>T p.T492S | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- WNT10A | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZCCHC12 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF140 | c.116A>C p.Y39S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- ZNF148 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 111/376 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ZNF275 | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- ZNF324B | c.848G>T p.R283L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ZNF644 | c.1668G>C p.M556I | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF658 | c.1018del p.H340Ifs*2 | Frame Shift Del (DEL) | VAF 48/127 reads (38%) | called by mutect2, pindel*, varscan2
- ZNF85 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- ABCC2 | c.3996G>C p.V1332= | Silent (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- ACOT12 | c.483T>C p.S161= | Silent (SNP) | VAF 61/62 reads (98%) | called by muse, mutect2, varscan2
- ALPK2 | c.3939C>T p.S1313= | Silent (SNP) | VAF 51/163 reads (31%) | called by muse, mutect2, varscan2
- C9orf43 | c.861A>G p.T287= | Silent (SNP) | VAF 43/87 reads (49%) | called by muse, mutect2, varscan2
- CBLN1 | c.150C>T p.A50= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV54655122; called by muse, mutect2
- CCDC60 | c.246G>A p.K82= | Silent (SNP) | VAF 120/211 reads (57%) | called by muse, mutect2, varscan2
- COL5A1 | c.4128C>T p.S1376= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs1034726142; called by muse, mutect2, varscan2
- CPAMD8 | c.1545A>G p.E515= (on ENST00000651564; = p.E468= on NM_015692.5) | Silent (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- CSMD3 | c.5481G>T p.L1827= (on ENST00000297405 / NM_001363185.1; = p.L1723= on NM_052900.3) | Silent (SNP) | VAF 128/316 reads (41%) | called by muse, mutect2, varscan2
- DCC | c.1755G>T p.L585= | Silent (SNP) | VAF 129/277 reads (47%) | called by muse, mutect2, varscan2
- DDR2 | c.1620G>T p.V540= | Silent (SNP) | VAF 42/165 reads (25%) | called by muse, varscan2
- DKK2 | c.294G>T p.S98= | Silent (SNP) | VAF 122/246 reads (50%) | catalogued as COSV99568177; called by muse, mutect2, varscan2
- DMP1 | c.681G>A p.R227= | Silent (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- DOCK11 | c.1878T>A p.V626= | Silent (SNP) | VAF 129/268 reads (48%) | called by muse, mutect2, varscan2
- FBXO15 | c.1497C>T p.I499= | Silent (SNP) | VAF 657/1334 reads (49%) | catalogued as rs772638453, COSV54043076; called by muse, mutect2, varscan2
- FCGR2A | c.234T>C p.N78= (on ENST00000271450 / NM_001136219.3; = p.N77= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/122 reads (57%) | catalogued as rs774178884; called by muse, mutect2, varscan2
- FRG2B | c.30C>G p.L10= | Silent (SNP) | VAF 44/201 reads (22%) | called by muse, mutect2, varscan2
- FRG2C | c.30C>G p.L10= | Silent (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- FRMPD4 | c.1441C>A p.R481= | Silent (SNP) | VAF 92/197 reads (47%) | catalogued as COSV66212807; called by muse, mutect2, varscan2
- HTR4 | c.183T>A p.S61= | Silent (SNP) | VAF 85/92 reads (92%) | catalogued as rs1307761509; called by muse, mutect2, varscan2
- IGKV1D-16 | c.183A>G p.K61= | Silent (SNP) | VAF 107/224 reads (48%) | catalogued as rs1366875317; called by muse, mutect2, varscan2
- KIAA1549L | c.4788G>C p.G1596= (on ENST00000321505; = p.G1893= on NM_012194.3) | Silent (SNP) | VAF 10/10 reads (100%) | called by muse, mutect2, varscan2
- KIF1B | c.5286G>A p.V1762= (on ENST00000377086 / NM_001365952.1; = p.V1716= on NM_015074.3) | Silent (SNP) | VAF 52/85 reads (61%) | called by muse, mutect2, varscan2
- LIN7C | c.291A>G p.P97= | Silent (SNP) | VAF 98/101 reads (97%) | catalogued as COSV53416267; called by muse, mutect2, varscan2
- LRP1B | c.11469A>T p.T3823= | Silent (SNP) | VAF 94/188 reads (50%) | called by muse, mutect2, varscan2
- MACF1 | c.1131A>G p.L377= | Silent (SNP) | VAF 59/114 reads (52%) | called by muse, mutect2, varscan2
- MAGEA6 | c.513C>T p.P171= | Silent (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- MFSD8 | c.261A>G p.Q87= | Silent (SNP) | VAF 21/319 reads (7%) | called by muse, mutect2
- MPO | c.1695G>A p.V565= | Silent (SNP) | VAF 86/90 reads (96%) | catalogued as rs775905828; called by muse, mutect2, varscan2
- MRPL13 | c.300A>T p.P100= | Silent (SNP) | VAF 68/151 reads (45%) | called by muse, mutect2, varscan2
- NLRP3 | c.546G>A p.E182= | Silent (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- OR2D3 | c.36G>A p.Q12= | Silent (SNP) | VAF 66/67 reads (99%) | catalogued as COSV58572538; called by muse, mutect2, varscan2
- PEX5 | c.1506G>A p.G502= (on ENST00000420616; = p.G494= on NM_000319.5) | Silent (SNP) | VAF 60/111 reads (54%) | catalogued as rs896760491; called by muse, mutect2, varscan2
- PLA2G5 | c.273G>A p.A91= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV64282829; called by muse, mutect2, varscan2
- POLR1B | c.882T>C p.C294= | Silent (SNP) | VAF 108/229 reads (47%) | called by muse, mutect2
- PRPH | c.801C>T p.D267= | Silent (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- PTCHD4 | c.1641A>T p.A547= | Silent (SNP) | VAF 29/48 reads (60%) | called by muse, mutect2, varscan2
- PTPRB | c.1845C>A p.S615= | Silent (SNP) | VAF 68/152 reads (45%) | catalogued as COSV54242792; called by muse, mutect2, varscan2
- PTPRT | c.3402G>T p.V1134= | Silent (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- ROBO1 | c.4863T>C p.N1621= | Silent (SNP) | VAF 107/115 reads (93%) | called by muse, mutect2, varscan2
- SETD1A | c.2106C>T p.A702= | Silent (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- SLC20A2 | c.672C>T p.L224= | Silent (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- SVEP1 | c.7389C>G p.L2463= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV52838797, COSV99929837, COSV99930084; called by muse, mutect2, varscan2
- SYNE1 | c.13596G>A p.V4532= (on ENST00000367255 / NM_182961.4; = p.V4461= on NM_033071.3) | Silent (SNP) | VAF 136/298 reads (46%) | called by muse, mutect2, varscan2
- TARS1 | c.1599C>T p.N533= | Silent (SNP) | VAF 85/293 reads (29%) | catalogued as COSV54307296; called by muse, mutect2, varscan2
- TFB2M | c.924T>C p.F308= | Silent (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- THSD7B | c.834C>G p.T278= | Silent (SNP) | VAF 54/135 reads (40%) | called by muse, mutect2, varscan2
- TLN2 | c.3789G>T p.R1263= | Silent (SNP) | VAF 50/107 reads (47%) | called by muse, mutect2, varscan2
- TTLL13P | c.646C>A p.R216= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV60036269; called by muse, mutect2, varscan2
- TTN | c.85554C>A p.P28518= (on ENST00000591111; = p.P21094= on NM_003319.4) | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV100632724; called by muse, mutect2, varscan2
- ZNF543 | c.615G>C p.G205= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as COSV100386806; called by muse, mutect2, varscan2
- H2BP2 | n.1062-352A>T | Intron (SNP) | VAF 84/359 reads (23%) | called by muse, mutect2, varscan2
- HMGN2P46 | n.909T>A | RNA (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- SSPOP | n.8723C>G | RNA (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- TTN | c.10360+1829T>A | Intron (SNP) | VAF 87/196 reads (44%) | called by muse, mutect2, varscan2
